Somatic mutation profile of tumor specimen TCGA-ZJ-AB0H-01A (aliquot TCGA-ZJ-AB0H-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AB0H, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Age at diagnosis: 48.9 years (17,869 days).
Specimen TCGA-ZJ-AB0H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d736578a-3ba2-47ae-a297-7c47e3c55426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AB0H-10A (Blood Derived Normal), aliquot TCGA-ZJ-AB0H-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c526fbd8-29a0-4885-9e59-c16de9e82ebe

The open-access MAF lists 120 somatic variants for this specimen: 87 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 32, Nonsense Mutation 4, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.5143C>T p.R1715* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as rs137852439, CM900094, CM920258, COSV64271015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABI3 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1405321081, COSV99865202; called by muse, mutect2
- ACE2 | c.1486A>G p.T496A | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99382510; called by muse, mutect2
- ADAMTSL1 | c.2981C>G p.T994S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV101001218; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2
- AFAP1L1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776907700, COSV57045908, COSV57049172; called by muse, mutect2, varscan2
- AGMO | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs756450306, COSV100693522; called by muse, mutect2, varscan2
- AKAP10 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as COSV99855242; called by muse, mutect2, varscan2
- ANKRD30A | c.650C>T p.S217L (on ENST00000611781; = p.S161L on NM_052997.2) | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100652842; called by muse, mutect2, varscan2
- AP1B1 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs574401859, COSV100434332; called by muse, mutect2, varscan2
- ASXL3 | c.1507G>C p.V503L | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1277633528, COSV99323185; called by muse, mutect2, varscan2
- ATP2C1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.897); catalogued as COSV100146221; called by muse, mutect2, varscan2
- CA4 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769858478, COSV99958187; called by mutect2, varscan2
- CAMSAP1 | c.3455G>A p.S1152N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100409544; called by muse, mutect2, varscan2
- CDH10 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as COSV100049919, COSV52591381; called by muse, mutect2
- CMYA5 | c.7531G>A p.D2511N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs767614826, COSV71407035; called by mutect2, varscan2
- COL12A1 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485334; called by muse, mutect2, varscan2
- COL1A1 | c.3994G>A p.D1332N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs754984293, COSV56807458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYGB | c.58T>G p.S20A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99505929; called by muse, mutect2, varscan2
- DENND4A | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101475253, COSV101475478; called by muse, mutect2
- DNMBP | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100143030; called by muse, mutect2, varscan2
- EGF | c.3557T>A p.L1186Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99490431; called by muse, mutect2, varscan2
- ELOA2 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99795827, COSV99796566; called by muse, mutect2, varscan2
- ERAP2 | c.2871G>A p.M957I | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101163487, COSV65940949; called by muse, mutect2, varscan2
- FLG2 | c.6029C>G p.S2010C | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV101165582; called by muse, mutect2, varscan2
- FLG2 | c.3329G>T p.G1110V | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV101165583, COSV101165691; called by muse, mutect2, varscan2
- FOXD3 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100942785; called by muse, mutect2, varscan2
- GBA | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1064648; called by muse, varscan2
- GCN1 | c.6700G>C p.E2234Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV100324610; called by muse, mutect2
- GFRA2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767947492, COSV100151356; called by muse, mutect2, varscan2
- GIGYF2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV101003830; called by muse, mutect2, varscan2
- GPR137C | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs766673125, COSV99908743; called by muse, mutect2, varscan2
- GTF2I | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100259415; called by muse, varscan2
- H4C13 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV60693656, COSV60694804; called by muse, mutect2, varscan2
- HMCN1 | c.4819C>G p.R1607G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs149151239, COSV54876205; called by muse, mutect2, varscan2
- HSPG2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs539990898, COSV101012868; called by muse, mutect2, varscan2
- HYDIN | c.51G>T p.L17F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.595); catalogued as COSV99861844; called by muse, mutect2, varscan2
- IRS4 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as COSV100929410; called by muse, mutect2, varscan2
- ITIH2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs548587256, COSV64434205; called by muse, mutect2, varscan2
- ITSN1 | c.4526C>G p.S1509* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV101181180; called by muse, mutect2, varscan2
- KCNT2 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99651274; called by muse, mutect2, varscan2
- LMF2 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752866373, COSV99327353; called by muse, mutect2, varscan2
- MAGEB4 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV100854598, COSV64396863; called by muse, mutect2, varscan2
- MIA3 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100719264; called by muse, mutect2
- MINDY3 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99510447; called by muse, mutect2, varscan2
- MTUS2 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs556525596, COSV101462059; called by muse, mutect2, varscan2
- MYL4 | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.611); catalogued as COSV100733071; called by mutect2, varscan2
- NLRP13 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.397); catalogued as COSV61620373; called by muse, mutect2, varscan2
- NLRP5 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs202235616; called by muse, mutect2, varscan2
- OR10H5 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100454625; called by muse, mutect2, varscan2
- OR1S1 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.164); catalogued as COSV100515224; called by muse, mutect2, varscan2
- OR52E2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs745479340, COSV58612078, COSV58612463; called by muse, mutect2, varscan2
- PAIP2B | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV54908973; called by muse, mutect2, varscan2
- PCDHB11 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.086); catalogued as rs1186123681, COSV100697123; called by muse, mutect2
- PDP2 | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305815; called by muse, mutect2
- PDXK | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV99376015; called by muse, mutect2, varscan2
- PPP2R3A | c.3219G>C p.Q1073H | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99386379; called by muse, mutect2, varscan2
- PUM1 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99927444; called by muse, mutect2, varscan2
- PWWP3B | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100530894; called by muse, mutect2, varscan2
- RGL3 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs113801365, COSV100992826; called by muse, mutect2, varscan2
- RIMS4 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1277817424, COSV65719391; called by muse, mutect2, varscan2
- RTN2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1286589568, COSV99838688; called by muse, mutect2, varscan2
- SELE | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100324462; called by muse, mutect2, varscan2
- SEMA6B | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.449); catalogued as COSV100014618; called by muse, mutect2, varscan2
- SETD2 | c.7178C>G p.P2393R | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100337901, COSV57449237; called by muse, mutect2, varscan2
- SLC24A4 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747743406, COSV100104091, COSV100104602; called by muse, mutect2, varscan2
- SMPX | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV101069725; called by muse, mutect2, varscan2
- SPP1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV99420815; called by muse, mutect2, varscan2
- SRBD1 | c.1518-1G>A p.X506_splice | Splice Site (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99764618; called by muse, mutect2, varscan2
- SRP72 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.776); catalogued as COSV100714240; called by muse, mutect2, varscan2
- TECTB | c.294C>A p.Y98* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV101027624; called by muse, mutect2, varscan2
- THSD7A | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.074); catalogued as rs767395309, COSV70273978; called by muse, mutect2, varscan2
- TIAM2 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs377169813; called by muse, mutect2, varscan2
- TMEM168 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV57179751; called by muse, mutect2, varscan2
- TOP1MT | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs764616681, COSV61316261; called by muse, mutect2, varscan2
- TRMT1L | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100834533; called by muse, mutect2
- TSPAN15 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100960218; called by muse, mutect2, varscan2
- TTN | c.96223G>T p.D32075Y (on ENST00000591111; = p.D24651Y on NM_003319.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | PolyPhen probably damaging (0.944); catalogued as COSV100592823; called by muse, mutect2, varscan2
- XIRP2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.714); catalogued as rs750812410, COSV99738035, COSV99746069; called by muse, mutect2, varscan2
- ZBTB20 | c.2202G>A p.M734I (on ENST00000474710 / NM_001164342.2; = p.M661I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV100612628; called by muse, mutect2
- ZMAT1 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as COSV100858661; called by muse, mutect2, varscan2
- ZNF516 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV71586885; called by muse, mutect2, varscan2
- ZNF81 | c.419A>T p.K140M | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV100095341; called by muse, mutect2, varscan2
- DNAH1 | c.4139A>G p.E1380G | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGBP1P2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SYNCRIP | c.412del p.T138Pfs*56 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- ADAM18 | c.1548C>T p.A516= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV99694772; called by muse, mutect2, varscan2
- AGTR2 | c.129T>C p.H43= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV100903525; called by muse, mutect2, varscan2
- BUD31 | c.396C>T p.I132= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs200813675, COSV52867845, COSV99463164; called by muse, mutect2, varscan2
- COBL | c.174G>A p.L58= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV54336958, COSV54342947; called by muse, mutect2, varscan2
- DDX21 | c.840C>T p.F280= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100826462; called by muse, mutect2, varscan2
- DISP1 | c.2250C>G p.S750= | Silent (SNP) | VAF 33/272 reads (12%) | catalogued as COSV99449803; called by muse, mutect2, varscan2
- DNER | c.756C>T p.L252= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100518227; called by muse, mutect2
- EIF5B | c.2319T>C p.A773= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as COSV99176776; called by muse, mutect2, varscan2
- ESCO1 | c.522T>C p.H174= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs772027945, COSV99331874; called by muse, mutect2, varscan2
- GPR149 | c.882G>A p.G294= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as rs1197218342, COSV101078087; called by muse, mutect2, varscan2
- HOGA1 | c.723C>G p.A241= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV101035501; called by muse, mutect2, varscan2
- KDM6A | c.1551G>A p.Q517= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100937878; called by muse, mutect2, varscan2
- KIAA0232 | c.1809G>A p.G603= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100300320; called by muse, mutect2, varscan2
- MAP4K1 | c.2250C>T p.T750= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV67713846; called by muse, mutect2
- MORC1 | c.2331C>G p.L777= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV51719179, COSV99224968; called by muse, mutect2
- MORC3 | c.312C>T p.F104= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV101264825; called by muse, mutect2, varscan2
- MYO5C | c.156C>G p.V52= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1185391371, COSV99954018; called by muse, mutect2, varscan2
- MYO7B | c.2625C>T p.F875= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1179234793, COSV101267861; called by muse, mutect2
- NEK3 | c.636C>G p.L212= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1228305139, COSV99317406, COSV99317434; called by muse, mutect2, varscan2
- PCSK6 | c.2382G>A p.Q794= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100623578; called by muse, mutect2, varscan2
- PLOD1 | c.1680C>T p.I560= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99537616; called by muse, mutect2
- PTPRD | c.5541C>T p.G1847= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1299879772, COSV61967550; called by muse, mutect2, varscan2
- SLC40A1 | c.1266G>A p.K422= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs775509346, COSV99656103; called by muse, mutect2, varscan2
- SLC5A8 | c.186C>T p.T62= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV101610511; called by muse, mutect2
- SMARCA5 | c.1386C>G p.L462= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99303412; called by muse, mutect2, varscan2
- TECRL | c.24C>T p.L8= | Silent (SNP) | VAF 15/189 reads (8%) | catalogued as rs1226729532, COSV67085470, COSV67087056; called by muse, mutect2
- TMEM165 | c.408C>T p.A136= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100820238; called by muse, mutect2, varscan2
- TMEM94 | c.2880C>T p.P960= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV100050070; called by muse, mutect2
- TRAK2 | c.958C>A p.R320= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV100216595; called by muse, mutect2, varscan2
- WDR24 | c.282C>T p.I94= (on ENST00000248142; = p.I32= on NM_032259.4) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99556269, COSV99556763; called by muse, mutect2
- ZKSCAN2 | c.2871G>A p.K957= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- ZNF462 | c.2799G>A p.T933= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs1025255211, COSV99470687; called by muse, mutect2, varscan2
- TCF12 | c.1189-834G>A | Intron (SNP) | VAF 9/56 reads (16%) | catalogued as rs765920481, COSV51019352, COSV99976380; called by muse, mutect2, varscan2
